Surgical pathology report (de-identified scan), TCGA case TCGA-DJ-A3US, project TCGA-THCA (Thyroid Carcinoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DJ-A3US-01A (Primary Tumor).

[page 1 of 2]
		4/30/12

ad & Neck
ad And Neck

Date of Procedure:
Date of Receipt:
Date of Report:
Account #:
Billing Type:
Additional Copy to:

Clinical Diagnosis & History:

year old with right FNA atypical cells.

Specimens Submitted:

- 1: Thyroid; total thyroidectomy
- 2: SP: Left paratracheal tissue

DIAGNOSIS:

1. Thyroid; total thyroidectomy:

Tumor Type: Papillary carcinoma, classical type

Histologic Grade: Well differentiated

Mitotic Activity: Not identified

Tumor Necrosis: Not identified

Other Tumor Features: Psammoma bodies

Tumor Location: Right lobe

Tumor Size: Greatest diameter is 1.5 cm.

Tumor Encapsulation: Partially surrounded

Blood Vessel Invasion: Not identified

Extrathyroid Extension: Not identified

Surgical Margins: Free of tumor

Tumor Multicentricity: Not identified

Non-Neoplastic Thyroid: Exhibits nodular hyperplasia

ICD-O-3

carcinoma, papillary, thyroid
8260/3

Site: thyroid, NOS

C73.9 5-2-12
KO

[page 2 of 2]
Parathyroid Glands:
Not identified

2. **Soft tissue, left paratracheal; biopsy:**
-benign fibroadipose tissue.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Special Studies:

Result

Special Stain
RECUT

Comment

Gross Description:

1). The specimen is received in formalin, labeled "total thyroidectomy, stitch marks right lobe of thyroid, fresh and sterile for" and consists of a 13.4 g thyroid. The right lobe measures 5 x 3.2 x 2.1 cm, the left lobe measures 4 x 1.6 x 1.5 cm and the isthmus measures 2 x 1.2 x 0.3 cm. The external surface is covered by a thin fibrous capsule. The posterior surface of the specimen is inked black, and the anterior is inked blue. Sectioning reveals a 1.5 x 1.2 x 1.2 cm ovoid, tan-brown, lobular, bulging nodule in the mid right pole. Sections through the remaining thyroid parenchyma reveals red-tan, meaty cut surfaces. A portion of the specimen is sent for Representative sections of the remaining tissue is submitted in ten cassettes.

Summary of sections:

N - nodule
RL - right lobe
LL - left lobe
IS - isthmus

2). The specimen is received in formalin, labeled, "left paratracheal tissue" and consists of a single irregular fragments of yellow-tan, rubbery soft tissue measuring 0.4 x 0.3 x 0.2 cm. The specimen is entirely submitted in one cassette.

Summary of sections:

U -- undesignated

Summary of Sections:

Part 1: Thyroid; total thyroidectomy

Block	Sect. Site	PCs
1	IS	2
2	LL	4
4	N	4
3	RL	3

Part 2: SP: Left paratracheal tissue

Block	Sect. Site	PCs
-------	------------	-----

Source: NCI Genomic Data Commons file ffc7a8fb-d362-483b-b675-8ac4b2090850 (TCGA-DJ-A3US.9994E892-85D5-4754-963E-16F0F3AEC2C2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).